Gene-level copy-number profile of specimen HCM-CSHL-0245-C18-85A from HCMI case HCM-CSHL-0245-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GB; Age at diagnosis: 72.9 years (26,617 days).
Specimen HCM-CSHL-0245-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0ca14d28-2d6f-4bac-a951-ee6f4276f507.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0245-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/4e9f9377-151e-431e-aba4-a8ea20f6d781

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,794; copy number 2: 48,294; copy number 3: 6,622; copy number 4: 1,668; copy number 5: 17.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:102,418,689–102,736,888, 7 genes, copy number 5: IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9.
- chr7:76,461,676–76,627,982, 9 genes, copy number 5 (within-gene range 3–5): DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1.
- chr9:107,963,703–107,964,045, 1 gene, copy number 5: RPS15AP27.

Autosomal genes at a single copy (total copy number 1): 1,794. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
